Somatic mutation profile of tumor specimen TCGA-HT-7609-01A (aliquot TCGA-HT-7609-01A-11D-2086-08) from TCGA case TCGA-HT-7609, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 34.5 years (12,607 days).
Specimen TCGA-HT-7609-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f9f841e-89c1-45b0-a101-5813a6eb055e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7609-10A (Blood Derived Normal), aliquot TCGA-HT-7609-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e37e7dc-434e-404c-9213-de69bb00eb64

The open-access MAF lists 25 somatic variants for this specimen: 22 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 20, Silent 3, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.28A>G p.K10E | Missense Mutation (SNP) | VAF 39/43 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs757280897, COSV63309287; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 43/100 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 13/25 reads (52%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.672+1G>A p.X224_splice | Splice Site (SNP) | VAF 16/40 reads (40%) | hotspot (GDC flag); catalogued as rs863224499, CS071266, CS123101, COSV52670407, COSV52712339, COSV52751788; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- CCDC69 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 13/131 reads (10%) | catalogued as rs371784207, COSV62599976; called by muse, mutect2
- CFAP54 | c.7169C>A p.A2390E | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV61575249; called by muse, mutect2, varscan2
- DOCK4 | c.523A>G p.I175V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs749266623, COSV70326476; called by muse, mutect2, varscan2
- FKBP7 | c.308T>C p.M103T | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs144779588, COSV51847586; called by muse, mutect2, varscan2
- GRIK2 | c.1801G>A p.V601M | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.327); catalogued as COSV59732401; called by muse, mutect2
- GRINA | c.944T>A p.L315Q | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57593589; called by muse, mutect2, varscan2
- ITGB1BP2 | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.14); catalogued as COSV52140282; called by muse, mutect2, varscan2
- KLHL30 | c.1532T>C p.L511P | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs563581501, COSV59978561; called by muse, mutect2
- LILRB2 | c.967G>T p.G323C | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.804); catalogued as COSV58748266; called by muse, mutect2
- LRP1 | c.11908G>A p.G3970R | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as rs1309594578, COSV54505506; called by muse, mutect2, varscan2
- MYH14 | c.461A>G p.Y154C | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51831251; called by muse, mutect2, varscan2
- OCRL | c.2059C>G p.L687V | Missense Mutation (SNP) | VAF 48/56 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63981865; called by muse, mutect2, varscan2
- PCBP2 | c.914G>A p.R305H (on ENST00000439930 / NM_001128911.2; = p.R306H on NM_005016.6) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV63727838; called by muse, mutect2, varscan2
- PJA2 | c.134T>G p.F45C | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63274598; called by muse, mutect2, varscan2
- SSBP2 | c.425C>A p.P142H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57804449; called by muse, mutect2, varscan2
- TNNI1 | c.269A>G p.N90S | Missense Mutation (SNP) | VAF 24/524 reads (5%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.98); catalogued as COSV60190477; called by muse, mutect2
- TTC23 | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV50444416; called by muse, mutect2
- EPHA8 | c.1688G>A p.C563Y | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.178); called by muse, mutect2
- FTMT | c.453C>T p.D151= | Silent (SNP) | VAF 13/153 reads (8%) | catalogued as COSV58420725; called by muse, mutect2
- KRT26 | c.717C>T p.N239= | Silent (SNP) | VAF 70/139 reads (50%) | catalogued as rs746798484, COSV59413738; called by muse, mutect2, varscan2
- SLC34A2 | c.1551G>A p.G517= | Silent (SNP) | VAF 75/177 reads (42%) | catalogued as rs761538283, COSV65943173; called by muse, mutect2, varscan2
